PECGS case C083-000072 — USC PE-CGS: Optimizing Engagement of Hispanic Colorectal Cancer Patients in Cancer Genomic Characterization Studies (PECGS-COPECC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon.
https://portal.gdc.cancer.gov/cases/6dbff5af-c41f-49ac-8775-efff5e9538a4

Demographics
Sex at birth: male; Age at index: 45 years; Year of birth: 1977; Education level: Some High School or Less.

Diagnoses (2)
1. Mucinous adenocarcinoma (the primary disease): ICD-O-3 morphology code: 8480/3; Tissue or organ of origin: Ascending colon; Age at diagnosis: 44.6 years (16,290 days); AJCC clinical stage: Stage IIIC; AJCC pathologic stage: Stage IIIC; Progression or recurrence: no.
2. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Age at diagnosis: 44.6 years (16,290 days); AJCC clinical stage: Stage IIIC; AJCC pathologic stage: Stage IIIB; Progression or recurrence: no.

Other clinical attributes
- BMI: 29.05.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Pack years smoked: 0; Alcohol history: Yes.

Biospecimens (2 samples)
- Sample C083-000072_Germline: Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample C083-000072_Tumor: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
